Somatic mutation profile of tumor specimen TCGA-CQ-5330-01A (aliquot TCGA-CQ-5330-01A-01D-1683-08) from TCGA case TCGA-CQ-5330, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 69.1 years (25,255 days).
Specimen TCGA-CQ-5330-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02810876-2a90-4788-8da5-0a47f932b97d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-5330-10A (Blood Derived Normal), aliquot TCGA-CQ-5330-10A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58d2d86b-ea9a-421b-90dc-1ed1b871a30f

The open-access MAF lists 64 somatic variants for this specimen: 48 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 41, Silent 16, Nonsense Mutation 4, In Frame Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1057519990, COSV52670619, COSV52672762, COSV52751844; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACTA1 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100796792; called by muse, mutect2
- ACTB | c.1016T>C p.V339A | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.904); catalogued as COSV100079912; called by muse, mutect2, varscan2
- ADAMTS4 | c.2488C>T p.R830W | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as rs114728887, COSV100917865; called by muse, mutect2, varscan2
- AGTPBP1 | c.2867T>G p.V956G (on ENST00000357081 / NM_001330701.2; = p.V916G on NM_015239.2) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100430165, COSV61278077; called by muse, mutect2, varscan2
- AHNAK | c.10981A>G p.M3661V | Missense Mutation (SNP) | VAF 59/245 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.31); catalogued as rs979971395, COSV99949295; called by muse, mutect2, varscan2
- ARL3 | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.431); catalogued as rs150077149; called by muse, mutect2, varscan2
- ATRN | c.1760C>T p.S587F | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99497763; called by muse, mutect2
- BAIAP2L2 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as COSV100207236; called by muse, mutect2, varscan2
- BMS1 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100996812; called by muse, mutect2, varscan2
- BSPRY | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.403); catalogued as rs758660546, COSV99445100; called by muse, mutect2, varscan2
- CACHD1 | c.344C>T p.T115M | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs751845549, COSV51557912; called by muse, mutect2, varscan2
- CBFA2T3 | c.500C>A p.P167Q | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1302539865, COSV99242325; called by muse, mutect2, varscan2
- CHD1 | c.1366-1G>A p.X456_splice | Splice Site (SNP) | VAF 19/79 reads (24%) | catalogued as COSV99399815; called by muse, mutect2, varscan2
- DNAH3 | c.6605G>A p.R2202Q | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1166904466, COSV99770161; called by muse, mutect2, varscan2
- DNAH5 | c.13456T>A p.F4486I | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99453388; called by muse, mutect2, varscan2
- DSG1 | c.2186C>T p.P729L | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV99936474; called by muse, mutect2, varscan2
- FEM1B | c.329A>G p.H110R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.044); catalogued as COSV100183748; called by muse, mutect2, varscan2
- FEZ1 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 8/76 reads (11%) | catalogued as COSV54032075, COSV99631062; called by muse, mutect2, varscan2
- FGF13 | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 43/231 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100264562; called by muse, mutect2, varscan2
- GGN | c.814G>A p.G272R | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.018); catalogued as COSV53056097; called by muse, mutect2, varscan2
- KSR2 | c.626A>G p.Y209C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.19); catalogued as rs368855606; called by muse, mutect2, varscan2
- LIFR | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV54689007; called by muse, mutect2, varscan2
- MAP1B | c.3107C>T p.P1036L | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs145156470; called by muse, mutect2, varscan2
- MUC16 | c.38939C>A p.P12980H | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.094); catalogued as COSV101201303; called by muse, mutect2, varscan2
- NAGS | c.809T>A p.V270E | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV99517974; called by muse, mutect2, varscan2
- NAPRT | c.1129G>A p.G377S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99435480; called by muse, mutect2, varscan2
- NCAPG | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs748530489, COSV99266144; called by muse, mutect2, varscan2
- OBSL1 | c.3618G>A p.W1206* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as COSV99217397; called by muse, mutect2, varscan2
- OMD | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs768130443, COSV65020176; called by muse, mutect2, varscan2
- RSPO3 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 29/91 reads (32%) | catalogued as rs773759447, COSV63150663; called by muse, mutect2, varscan2
- SAMD9L | c.2926G>A p.V976I | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV59080949; called by muse, mutect2, varscan2
- SEC16A | c.1009C>T p.L337F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as rs760444762, COSV99260058; called by mutect2, varscan2
- SENP7 | c.1787A>G p.Y596C | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100053791; called by muse, mutect2
- SLC26A8 | c.2393G>T p.R798M | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100839592; called by muse, mutect2, varscan2
- STK26 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV100688863; called by muse, mutect2, varscan2
- TAL1 | c.811G>T p.G271* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV53745987, COSV99595897; called by muse, mutect2, varscan2
- TLL1 | c.2665G>A p.G889R | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376169735; called by muse, mutect2, varscan2
- TMEM72 | c.559A>G p.K187E | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.442); catalogued as COSV101273569; called by muse, mutect2, varscan2
- TNR | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV99691247; called by muse, mutect2, varscan2
- TSHZ1 | c.2005G>A p.A669T (on ENST00000580243 / NM_001308210.2; = p.A624T on NM_005786.6) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV100433909; called by muse, mutect2, varscan2
- TUSC3 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as rs367660078, COSV65878877; called by muse, mutect2, varscan2
- ZFHX4 | c.9691A>G p.K3231E | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.6); catalogued as COSV99266774; called by muse, mutect2
- ZNF208 | c.629T>C p.F210S | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101237185; called by muse, mutect2, varscan2
- ZNF648 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV60571796; called by muse, mutect2, varscan2
- ZNF711 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV99341515; called by muse, mutect2, varscan2
- CDKN2A | c.299_313del p.A100_L104del | In Frame Del (DEL) | VAF 19/45 reads (42%) | called by mutect2, pindel, varscan2
- HUWE1 | c.12610_12612del p.K4204del | In Frame Del (DEL) | VAF 15/64 reads (23%) | called by pindel, varscan2
- C18orf54 | c.756C>T p.P252= | Silent (SNP) | VAF 44/183 reads (24%) | catalogued as rs374556847, COSV55619144; called by muse, mutect2, varscan2
- CKAP2L | c.918T>C p.N306= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV100198752; called by muse, mutect2, varscan2
- GJB3 | c.78C>T p.S26= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as rs1002411368; called by muse, mutect2
- ILF3 | c.954G>A p.A318= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs150021624; called by muse, mutect2
- PCDHA13 | c.2196C>T p.C732= | Silent (SNP) | VAF 37/119 reads (31%) | catalogued as rs782120132, COSV56542708, COSV56557456; called by muse, mutect2, varscan2
- PHKB | c.1404G>A p.Q468= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV100068340; called by muse, mutect2, varscan2
- PPP5C | c.621A>G p.K207= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV99183649; called by muse, mutect2, varscan2
- PSMD11 | c.483C>T p.D161= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs1383430341, COSV55578408; called by muse, mutect2, varscan2
- RALYL | c.705G>A p.L235= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as COSV101569417; called by muse, mutect2
- RBM47 | c.660G>A p.Q220= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as COSV99921485; called by muse, mutect2, varscan2
- SP110 | c.930G>A p.K310= | Silent (SNP) | VAF 31/122 reads (25%) | catalogued as COSV99283739; called by muse, mutect2, varscan2
- SUV39H1 | c.273G>A p.K91= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs782249211, COSV61921331; called by muse, mutect2
- WDFY1 | c.918G>C p.T306= | Silent (SNP) | VAF 66/315 reads (21%) | catalogued as COSV99239821; called by muse, varscan2
- ZBTB33 | c.1506A>G p.S502= | Silent (SNP) | VAF 13/139 reads (9%) | catalogued as COSV100434305; called by muse, mutect2
- ZNF587 | c.468G>A p.S156= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs773413838, COSV57150077; called by mutect2, varscan2
- ZNF616 | c.612G>A p.Q204= | Silent (SNP) | VAF 44/141 reads (31%) | catalogued as COSV100348564; called by muse, mutect2, varscan2
